Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3429, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3429-01A (Primary Tumor).

[page 1 of 2]
Clinical History/Diagnosis: Left renal mass.

Source of Specimen(s):

A: Lymph Node, para aortic

B: Right kidney

C: Lymph Node, additional para aortic

Gross Description:

Received in three parts.

Source of Tissue: 1. Labeled #1 "para-aortic lymph node"

Gross Description: The specimen is received fresh and consists of three pinkish-red potential lymph nodes measuring respectively 0.7, 0.9 and 1.4 cm. They are submitted in toto in 1A.

Designation of Sections:

Summary of Sections:

Source of Tissue: 2. Labeled #2 "right kidney and para-aortic lymph node"

Frozen Section Diagnosis: 2FS RENAL CELL CARCINOMA

Gross Description: The specimen is received fresh and consists of a 200 gm kidney measuring 12.5 x 7 x 5 cm. A scant amount of fibrofatty perirenal fat is present measuring up to 3 cm from point of attachment. No lesions, masses or nodes are found in the fat. The segment of ureter is present measuring 8 x 0.4 cm. The ureter is opened revealing the usual surface with no suspicious lesions. The vascular margins are grossly free of lesions or masses. No adrenal gland is found. The specimen is bivalved revealing a yellowish-orange soft tumor comprising the middle and superior aspect of the kidney measuring 7.5 x 6 x 5 cm. The lesion grossly pushes on the capsule, however, no invasion is present. The superior calyx is replaced by tumor. The middle and inferior calyx are uninvolved by tumor. The pelvis is also uninvolved by lesion. One representative section from the tumor was selected for frozen section consultation submitted in 2FS.

Designation of Sections: 2A ureter/vascular margin, 2B-2C tumor in relationship to capsule, 2D tumor with adjacent normal kidney and middle calyx, 2E uninvolved lower pole kidney, 2F-2H perinephric fat

Summary of Sections: 2A-2H

Source of Tissue: 3. Labeled #3 "additional para-aortic lymph node"

Gross Description: The specimen is received fresh and consists of two

[page 2 of 2]
pinkish-red rubbery nodes measuring respectively 1.7 x 0.9 x 0.6 and 2.3 x 1 x 0.6 cm. Submitted in toto in 3A.

Designation of Sections:

Summary of Sections:

Final Diagnosis:

1. Para-aortic lymph node (excision):

- Three lymph nodes negative for metastatic carcinoma (0/3).

2. Kidney, right, and para-aortic lymph nodes (nephrectomy):

- Renal cell carcinoma (7.5 cm), clear cell (conventional) type, [REDACTED] nuclear grade 2, limited to the kidney, invading into, but not through the renal capsule.
- Negative vascular and ureteral margins.

3. Additional para-aortic lymph nodes (excision):

- Two lymph nodes negative for metastatic carcinoma (0/2).
- Stage pT2N0.

Source: NCI Genomic Data Commons file 5420b1ba-2c62-4ca2-b356-71275590a2ca (TCGA-AK-3429.79567CAB-FA8D-43B3-ABEF-EDF36040C3F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).